Somatic mutation profile of tumor specimen TCGA-14-1821-01A (aliquot TCGA-14-1821-01A-01W-0643-08) from TCGA case TCGA-14-1821, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,329 days).
Specimen TCGA-14-1821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b33a430-7ced-464c-802e-8b8755dcb87c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1821-10A (Blood Derived Normal), aliquot TCGA-14-1821-10A-01W-0644-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf243734-2c6a-4d55-9b84-5700cd205e6d

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 63/140 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PDGFRA | c.1977C>G p.N659K | Missense Mutation (SNP) | VAF 138/197 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519700, COSV57264866, COSV57265972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 174/190 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2875A>G p.I959V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.371); catalogued as COSV101036603; called by muse, mutect2, varscan2
- AGTPBP1 | c.1829C>A p.S610* (on ENST00000357081 / NM_001330701.2; = p.S570* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 109/360 reads (30%) | catalogued as COSV100429319; called by muse, mutect2, varscan2
- ARAF | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as rs1345707414, COSV51691626; called by muse, mutect2, varscan2
- ARMC4 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763662864, COSV100537114, COSV59456453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE5 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs751882671, COSV99782478; called by muse, mutect2, varscan2
- CRISP3 | c.763A>G p.T255A (on ENST00000371159 / NM_001368123.1; = p.T237A on NM_006061.4) | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99538643; called by muse, mutect2
- F8 | c.3845A>T p.K1282I | Missense Mutation (SNP) | VAF 167/172 reads (97%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100811294; called by muse, mutect2, varscan2
- GRHL2 | c.1473G>C p.Q491H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99306172; called by muse, mutect2, varscan2
- MMEL1 | c.1143G>T p.Q381H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99983337; called by muse, mutect2, varscan2
- MYT1 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100114058; called by muse, mutect2, varscan2
- NEIL1 | c.336_337del p.C113Ffs*42 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs1435000281; called by mutect2, varscan2
- SENP7 | c.389T>G p.V130G | Missense Mutation (SNP) | VAF 179/394 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100052593; called by muse, mutect2, varscan2
- SYNE2 | c.19447T>G p.S6483A | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100646853, COSV59961076; called by muse, mutect2, varscan2
- ATRX | c.882_883del p.N294Kfs*7 | Frame Shift Del (DEL) | VAF 111/150 reads (74%) | called by mutect2, pindel, varscan2
- DNAJC14 | c.138T>G p.A46= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57913985; called by muse, mutect2, varscan2
- RSU1 | c.663C>A p.P221= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV100590248; called by muse, mutect2, varscan2
- SF3B1 | c.2868T>A p.S956= | Silent (SNP) | VAF 94/205 reads (46%) | catalogued as COSV100133918; called by muse, mutect2, varscan2
- CPLANE1 | c.*2724A>G | 3'UTR (SNP) | VAF 135/245 reads (55%) | catalogued as COSV99949794; called by muse, mutect2, varscan2
